Somatic mutation profile of tumor specimen MMRF_1543_1_BM_CD138pos (aliquot MMRF_1543_1_BM_CD138pos_T2_KHS5U_K14089) from MMRF case MMRF_1543, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,046 days).
Specimen MMRF_1543_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adf7aff6-9061-4704-b090-1d814c337ede.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1543_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1543_1_PB_Whole_C1_KHS5U_K14078; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/017a9282-04d8-4ab0-9c8b-d716efc0065a

The open-access MAF lists 100 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 26, Intron 13, Silent 12, 5'UTR 4, 5'Flank 4, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 138/561 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACADL | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs949468130; called by muse, mutect2, varscan2
- ACAN | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 73/375 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs748422617, COSV61364804; called by muse, mutect2, varscan2
- CD96 | c.1516C>T p.H506Y (on ENST00000283285 / NM_198196.3; = p.H490Y on NM_005816.5) | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs945290958; called by muse, mutect2, varscan2
- IGHV1-24 | c.200T>A p.M67K | Missense Mutation (SNP) | VAF 102/108 reads (94%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs543536369; called by muse, mutect2, varscan2
- IGHV2-70 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs747883300; called by muse, varscan2
- IGKJ3 | c.10T>A p.F4I | Missense Mutation (SNP) | VAF 26/156 reads (17%) | catalogued as rs72847528; called by muse, varscan2
- ITGA2 | c.1996dup p.I666Nfs*24 | Frame Shift Ins (INS) | VAF 11/51 reads (22%) | catalogued as rs754302389; called by mutect2, pindel, varscan2
- LAMA3 | c.9161A>T p.K3054I (on ENST00000313654 / NM_198129.4; = p.K1445I on NM_000227.6) | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52537459; called by muse, varscan2
- LIPC | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.133); catalogued as rs1198482131; called by muse, mutect2, varscan2
- OR10J5 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58387454, COSV58387968; called by muse, mutect2, varscan2
- REC114 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1172575671, COSV58521574; called by muse, mutect2, varscan2
- RIPK4 | c.1102C>T p.R368W (on ENST00000352483; = p.R320W on NM_020639.3) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs750978256; called by muse, varscan2
- SEMA3D | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1265790609, COSV52387550; called by muse, mutect2, varscan2
- SLC8A2 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 98/176 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1568448114; called by muse, mutect2, varscan2
- TNXB | c.7549C>T p.R2517C (on ENST00000647633; = p.R2270C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1454433703; called by muse, mutect2, varscan2
- ABHD17B | c.449G>C p.W150S | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CLIP2 | c.2609T>C p.L870P | Missense Mutation (SNP) | VAF 118/170 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- CUX2 | c.3036C>G p.N1012K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- DDR1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- DNAJB7 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DSPP | c.345del p.A116Qfs*25 | Frame Shift Del (DEL) | VAF 94/225 reads (42%) | called by mutect2, pindel, varscan2
- GPR26 | c.911G>C p.S304T | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRIN2 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- HOXA5 | c.526A>T p.I176F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HSPB2 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- LAMA2 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA3 | c.9156dup p.K3053Efs*13 (on ENST00000313654 / NM_198129.4; = p.K1444Efs*13 on NM_000227.6) | Frame Shift Ins (INS) | VAF 49/154 reads (32%) | called by pindel, varscan2
- MIS18BP1 | c.658+2T>C p.X220_splice | Splice Site (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- NT5DC3 | c.1292G>A p.W431* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- PGAM1 | c.65T>C p.F22S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PLCB1 | c.81A>T p.K27N | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PODXL | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PPP3R1 | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RBM17 | c.1126T>A p.Y376N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- RPH3A | c.1733C>A p.A578D (on ENST00000389385 / NM_001143854.2; = p.A574D on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPNS2 | c.1344+2T>C p.X448_splice | Splice Site (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- STXBP5L | c.160_161del p.L54Dfs*25 | Frame Shift Del (DEL) | VAF 24/89 reads (27%) | called by mutect2, pindel, varscan2
- TMTC1 | c.1625A>G p.Q542R (on ENST00000539277 / NM_001193451.2; = p.Q434R on NM_175861.3) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- USP45 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF703 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- ACSBG1 | c.72C>A p.T24= | Silent (SNP) | VAF 43/175 reads (25%) | called by muse, mutect2, varscan2
- AKNAD1 | c.1335C>T p.V445= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as rs1206303450; called by muse, mutect2, varscan2
- B3GAT2 | c.672C>T p.N224= | Silent (SNP) | VAF 66/218 reads (30%) | catalogued as rs371527631, COSV57769270; called by muse, mutect2, varscan2
- GPR32 | c.828G>C p.L276= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs761389276; called by muse, mutect2, varscan2
- GREB1 | c.3975C>T p.Y1325= | Silent (SNP) | VAF 61/253 reads (24%) | catalogued as rs371137407; called by muse, mutect2, varscan2
- INO80C | c.396T>G p.A132= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- OR6T1 | c.618G>A p.V206= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs760099031; called by muse, mutect2, varscan2
- PPFIA4 | c.204C>A p.L68= | Silent (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- RNF146 | c.633T>C p.S211= (on ENST00000368314 / NM_001242850.2; = p.S210= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- UBAP1L | c.600G>T p.P200= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- XAGE3 | c.24A>C p.T8= | Silent (SNP) | VAF 25/179 reads (14%) | called by muse, mutect2, varscan2
- ZNF274 | c.1506G>A p.K502= (on ENST00000610905; = p.K397= on NM_016324.3) | Silent (SNP) | VAF 48/236 reads (20%) | catalogued as rs267605738; called by muse, mutect2, varscan2
- AADACL2 | c.*87A>T | 3'UTR (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.*560A>T | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- AMER3 | c.*907T>C | 3'UTR (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- BEND7 | c.*468C>T | 3'UTR (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- BMP7 | c.-230G>T | 5'UTR (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- CACNG8 | c.*1409G>T | 3'UTR (SNP) | VAF 119/247 reads (48%) | called by muse, mutect2, varscan2
- CCN1 | c.63+118G>A | Intron (SNP) | VAF 50/144 reads (35%) | called by muse, mutect2, varscan2
- CD47 | c.*1842T>C | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- CUL5 | c.-379C>T | 5'UTR (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- CYP2B7P | n.699+63A>G | Intron (SNP) | VAF 60/212 reads (28%) | called by muse, mutect2, varscan2
- CYP4F2 | c.985+68A>G | Intron (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- DLX3 | c.*684C>T | 3'UTR (SNP) | VAF 19/49 reads (39%) | catalogued as rs1240900908, COSV101460592; called by muse, mutect2, varscan2
- DUSP15 | c.426+1400G>A | Intron (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- DZIP1 | c.*3896A>T | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- ENTPD4 | c.*2684T>G | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- GALNT17 | c.*103G>T | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- GDF2 | c.*130C>T | 3'UTR (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- GNG11 | c.-324G>C | 5'UTR (SNP) | VAF 56/176 reads (32%) | called by muse, mutect2, varscan2
- HTR2A | c.*82A>G | 3'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- KCTD16 | c.*3001A>T | 3'UTR (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- LSM8 | c.31+413A>C | Intron (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- LYPD6 | c.*1729T>C | 3'UTR (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- MAGI3 | c.-294T>A | 5'UTR (SNP) | VAF 56/87 reads (64%) | called by muse, mutect2, varscan2
- MID1 | c.757-10592G>A | Intron (SNP) | VAF 23/25 reads (92%) | called by muse, mutect2
- MIR5787 | chr3:50227003 C>A | 5'Flank (SNP) | VAF 49/194 reads (25%) | called by muse, mutect2, varscan2
- NKTR | c.4200-75A>G | Intron (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- NQO1 | c.*1203_*1205del | 3'UTR (DEL) | VAF 22/52 reads (42%) | called by pindel, varscan2
- PLEKHG4B | c.*1123C>T | 3'UTR (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2
- PPP3R2 | c.*1820C>T | 3'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- PTGR1 | chr9:111603042 G>C | 5'Flank (SNP) | VAF 66/252 reads (26%) | called by muse, mutect2, varscan2
- SCN1A | c.*2061A>G | 3'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- SEMA3D | c.861+5290T>G | Intron (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- SIM1 | c.*1407dup | 3'UTR (INS) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- SLC37A1 | c.*562G>A | 3'UTR (SNP) | VAF 98/262 reads (37%) | catalogued as rs1007838370; called by muse, mutect2, varscan2
- SLC5A1 | c.*807dup | 3'UTR (INS) | VAF 25/61 reads (41%) | called by mutect2, pindel, varscan2
- SOX11 | c.*795G>A | 3'UTR (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2863+32A>G | Intron (SNP) | VAF 39/53 reads (74%) | called by muse, mutect2, varscan2
- THRA | c.1111-1077G>T | Intron (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- TMSB4X | chrX:12975536 C>G | 5'Flank (SNP) | VAF 64/69 reads (93%) | catalogued as COSV66081566; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975637 T>A | 5'Flank (SNP) | VAF 78/82 reads (95%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+84G>T | Intron (SNP) | VAF 60/64 reads (94%) | called by muse, varscan2
- TMSB4X | c.-17+159A>T | Intron (SNP) | VAF 52/54 reads (96%) | called by muse, varscan2
- UMODL1 | c.1300-251G>A | Intron (SNP) | VAF 61/204 reads (30%) | called by muse, mutect2, varscan2
- VWDE | c.*175G>A | 3'UTR (SNP) | VAF 30/83 reads (36%) | catalogued as rs1285291829; called by muse, mutect2, varscan2
- ZDHHC17 | c.*545A>G | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- ZNF583 | c.*258A>C | 3'UTR (SNP) | VAF 5/108 reads (5%) | called by muse, mutect2
- ZNF829 | c.*1637G>A | 3'UTR (SNP) | VAF 33/143 reads (23%) | catalogued as rs1056220009; called by muse, mutect2, varscan2
